CCDI case PBCAMH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/fbf8e7a4-cf5c-4d35-b517-3a44710c473a

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.8 years (5,764 days).

Biospecimens (3 samples)
- Sample 0DMEU0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMEUI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMEUM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
